Gene-level copy-number profile of tumor specimen ALCH-B2AX-TTP1-A from ALCHEMIST case ALCH-B2AX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 41.6 years (15,180 days).
Specimen ALCH-B2AX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dd390f20-69c0-4977-a2b9-51eae8b1b442.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2AX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,754 have no estimate.
https://portal.gdc.cancer.gov/files/ff24b697-c792-41f5-b8a9-1ca766511e67

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 173; copy number 1: 14,434; copy number 2: 41,769; copy number 3: 2,428; copy number 4: 27; copy number 5: 3; copy number 6: 1; copy number 7: 18; copy number 8: 7; copy number 9: 1; copy number 10: 3; copy number 12: 1; copy number 23: 2; copy number 36: 2.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:220,879,431–220,885,059, 1 gene (within-gene range 0–2): HLX.
- chr2:42,511,570–42,533,442, 2 genes (within-gene range 0–2): Metazoa_SRP, AC025750.1.
- chr2:90,121,786–90,173,414, 4 genes: IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11.
- chr2:91,736,726–91,781,169, 4 genes: AC027612.1, KMT5AP2, AC027612.3, GGT8P.
- chr2:232,649,849–232,650,136, 1 gene (within-gene range 0–1): RN7SL359P.
- chr3:49,674,014–49,689,501, 3 genes (within-gene range 0–1): APEH, MST1, AC099668.1.
- chr3:49,857,988–49,930,173, 7 genes: CAMKV, RN7SL217P, ACTBP13, MST1R, AC105935.2, AC105935.1, MON1A.
- chr4:4,117,925–4,127,569, 2 genes: AC116562.1, OR7E103P.
- chr7:129,953,234–130,026,989, 2 genes (within-gene range 0–2): AC073320.1, Y_RNA.
- chr7:156,944,721–156,945,645, 1 gene: AC006357.1.
- chr8:123,180,310–123,182,788, 2 genes (within-gene range 0–2): U3, AC068228.1.
- chr9:129,738,331–129,753,042, 1 gene: PTGES.
- chr10:11,849,608–11,894,700, 1 gene (within-gene range 0–2): PROSER2-AS1.
- chr11:45,909,663–45,929,096, 2 genes: PEX16, LARGE2.
- chr11:70,603,304–70,604,859, 1 gene (within-gene range 0–1): AP001271.2.
- chr15:25,174,927–25,191,497, 10 genes (within-gene range 0–1): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12.
- chr15:25,209,918–25,225,284, 9 genes (within-gene range 0–1): SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:63,890,030–63,890,317, 1 gene: AC015914.2.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr15:76,993,359–77,037,475, 1 gene: PSTPIP1.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr17:39,603,536–39,609,777, 1 gene: NEUROD2.
- chr18:79,395,856–79,529,325, 6 genes (within-gene range 0–1): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.
- chr19:54,415,219–54,436,904, 3 genes (within-gene range 0–1): TTYH1, AC245884.1, AC245884.9.
- chr19:57,230,802–57,262,728, 2 genes (within-gene range 0–2): AURKC, ZNF805.
- chr20:3,227,417–3,245,382, 2 genes: SLC4A11, AL109976.1.
- chr21:8,762,386–9,129,752, 12 genes: CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:43,053,191–43,076,943, 1 gene: CBS.
- chr22:19,045,256–19,048,375, 2 genes (within-gene range 0–2): Y_RNA, DGCR11.
- chr22:41,909,554–41,958,933, 5 genes: SHISA8, TNFRSF13C, MIR378I, CENPM, LINC00634.
- chr22:47,115,838–47,117,217, 1 gene (within-gene range 0–2): FP325331.1.
- chr22:50,343,304–50,475,035, 2 genes: PPP6R2, SBF1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,429,827–130,441,413, 1 gene, copy number 5 (within-gene range 2–5): CYP4F62P.
- chr4:9,034,519–9,381,269, 1 gene, copy number 7 (within-gene range 2–7): AC108519.1.
- chr4:9,234,385–9,236,046, 1 gene, copy number 7: USP17L15.
- chr4:9,253,378–9,369,070, 15 genes, copy number 7: USP17L19, USP17L20, USP17L21, USP17L22, USP17L23, USP17L24, USP17L25, USP17L26, USP17L5, USP17L27, USP17L28, USP17L29, USP17L9P, USP17L30, USP17L6P.
- chr7:75,391,955–75,410,996, 2 genes, copy number 23 (within-gene range 4–23): AC211486.1, TRIM73.
- chr8:143,368,876–143,384,221, 1 gene, copy number 6: RHPN1.
- chr11:1,991,096–2,001,470, 5 genes, copy number 8: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr12:52,022,832–52,059,507, 1 gene, copy number 5 (within-gene range 2–5): NR4A1.
- chr14:104,857,792–104,858,836, 1 gene, copy number 12: AL583810.1.
- chr21:43,140,523–43,141,092, 1 gene, copy number 7: FRGCA.
- chr22:18,615,581–18,719,341, 5 genes, copy number 8–36: Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.
- chr22:21,103,016–21,142,371, 4 genes, copy number 5–10: BCRP2, AP000550.1, POM121L7P, E2F6P2.

Autosomal genes at a single copy (total copy number 1): 11,690. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
